Somatic mutation profile of tumor specimen TCGA-V1-A8ML-01A (aliquot TCGA-V1-A8ML-01A-11D-A377-08) from TCGA case TCGA-V1-A8ML, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af01d951-a235-4dae-b54a-120e02e6a9fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8ML-10A (Blood Derived Normal), aliquot TCGA-V1-A8ML-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8bce794-9d4c-4b64-a36d-303141ea2870

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO4 | c.1138G>T p.D380Y (on ENST00000392977 / NM_001286615.2; = p.D345Y on NM_178826.4) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100153117; called by muse, mutect2, varscan2
- DAAM1 | c.18A>C p.R6S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100658497; called by muse, mutect2, varscan2
- FRYL | c.3172C>T p.H1058Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV99977310; called by muse, mutect2, varscan2
- KDM6A | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100938339; called by muse, mutect2, varscan2
- RIC3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.124); catalogued as COSV100112132; called by muse, mutect2, varscan2
- ASH1L | c.6137dup p.R2047Efs*3 (on ENST00000368346 / NM_001366177.2; = p.R2042Efs*3 on NM_018489.3) | Frame Shift Ins (INS) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- SPEN | c.3066_3081del p.S1023Ffs*3 | Frame Shift Del (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- AKAP12 | c.2178C>T p.D726= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs754437547, COSV53576358; called by muse, mutect2, varscan2
- CAD | c.480A>G p.P160= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99255273; called by muse, mutect2, varscan2
